Somatic mutation profile of tumor specimen HCM-CSHL-0182-C25-01A (aliquot HCM-CSHL-0182-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0182-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.6 years (27,264 days).
Specimen HCM-CSHL-0182-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41f91eaf-57fb-425d-b641-257b96e191e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0182-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0182-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03dc9551-3db5-43e2-9b72-116898437fd1

The open-access MAF lists 58 somatic variants for this specimen: 37 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, 5'UTR 2, Nonsense Mutation 2, Intron 2, 5'Flank 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 68/276 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 68/324 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1334037274, COSV66309951; called by muse, mutect2, varscan2
- ADGRG4 | c.3869G>T p.G1290V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV54954574; called by muse, mutect2, varscan2
- ALPP | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 49/698 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs755952363, COSV67397383; called by muse, mutect2
- ATXN7L1 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV66300240; called by muse, mutect2, varscan2
- CDH10 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52578279; called by muse, mutect2
- CHRNB2 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 113/517 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as rs778714852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHL1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as COSV61780230, COSV61780414; called by muse, mutect2, varscan2
- GRAMD4 | c.1635G>A p.P545= | Splice Region (SNP) | VAF 26/203 reads (13%) | catalogued as rs148851544; called by muse, mutect2, varscan2
- KL | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as rs757477654; called by muse, mutect2, varscan2
- LRRC4C | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347112092, COSV53417483; called by muse, mutect2
- OGDHL | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 66/611 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs369109768, COSV65105105; called by muse, mutect2, varscan2
- OR8B8 | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); catalogued as rs76671561, COSV60144065; called by muse, mutect2
- PLEKHG4B | c.13C>T p.R5W (on ENST00000283426; = p.R361W on NM_052909.5) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1039069776, COSV52056311; called by muse, mutect2
- RADIL | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs746063859, COSV68199784; called by muse, mutect2
- RNF207 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs770911105; called by muse, mutect2
- ROBO3 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010020965; called by muse, mutect2, varscan2
- SPATA31D1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 45/592 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs765399068, COSV61196397; called by muse, mutect2
- SPATC1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs527279030, COSV66298471; called by muse, mutect2, varscan2
- STK3 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs766490046; called by muse, mutect2
- WDR3 | c.2234T>G p.F745C | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60452263; called by muse, mutect2
- CDKN2A | c.310_311insGCGGT p.L104Rfs*44 | Frame Shift Ins (INS) | VAF 164/640 reads (26%) | called by mutect2, varscan2
- DCHS1 | c.9866A>G p.E3289G | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- EFTUD2 | c.1720del p.A574Lfs*7 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel
- HOXB3 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- HSF1 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KRT80 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, varscan2
- KRT80 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- MYO1H | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSBPL7 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PDLIM7 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- PLEKHA1 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLD1 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNFRSF6B | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 77/313 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- UNC93B1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF528 | c.64T>A p.W22R | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD2 | c.261G>A p.L87= | Silent (SNP) | VAF 33/210 reads (16%) | catalogued as rs144778680; called by muse, mutect2, varscan2
- APIP | c.267G>A p.S89= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs781461162, COSV53506559; called by muse, mutect2, varscan2
- CDH15 | c.1248C>T p.Y416= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as rs771303296; called by muse, mutect2
- CGB1 | c.138C>T p.T46= | Silent (SNP) | VAF 89/622 reads (14%) | catalogued as rs765381688; called by muse, varscan2
- CMIP | c.1308C>T p.P436= (on ENST00000537098 / NM_198390.2; = p.P342= on NM_030629.3) | Silent (SNP) | VAF 18/262 reads (7%) | catalogued as rs747368835, COSV67700291; called by muse, mutect2
- CNGB1 | c.1041G>T p.L347= | Silent (SNP) | VAF 28/573 reads (5%) | called by muse, mutect2
- DGKZ | c.39C>T p.S13= | Silent (SNP) | VAF 23/446 reads (5%) | catalogued as rs1249768235; called by muse, mutect2
- FMN1 | c.1734G>A p.K578= | Silent (SNP) | VAF 60/279 reads (22%) | called by muse, mutect2, varscan2
- KIAA1217 | c.570G>A p.Q190= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs745540023; called by muse, mutect2
- MECOM | c.687G>C p.T229= (on ENST00000468789 / NM_001105078.4; = p.T417= on NM_004991.4) | Silent (SNP) | VAF 23/194 reads (12%) | called by muse, mutect2, varscan2
- NAV1 | c.1515T>G p.P505= | Silent (SNP) | VAF 140/439 reads (32%) | called by muse, mutect2, varscan2
- POLA1 | c.2391C>T p.Y797= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as rs201734540; called by muse, mutect2, varscan2
- POM121L12 | c.282C>T p.S94= | Silent (SNP) | VAF 69/240 reads (29%) | catalogued as rs1038709836, COSV68692409; called by muse, mutect2, varscan2
- RASAL3 | c.894C>T p.N298= | Silent (SNP) | VAF 58/447 reads (13%) | called by muse, mutect2, varscan2
- SALL2 | c.1293G>A p.Q431= | Silent (SNP) | VAF 29/277 reads (10%) | called by muse, mutect2, varscan2
- TRPM3 | c.4614C>T p.N1538= (on ENST00000357533 / NM_001366142.2; = p.N1393= on NM_020952.6) | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs1282218990, COSV62582505; called by muse, mutect2, varscan2
- CAPRIN2 | c.2148+1672A>G | Intron (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- PRDM16 | chr1:3067555 G>A | 5'Flank (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- RPL37A | c.-21T>C | 5'UTR (SNP) | VAF 23/237 reads (10%) | catalogued as rs781242814; called by muse, mutect2, varscan2
- SEC14L1 | c.2042+68del | Intron (DEL) | VAF 39/118 reads (33%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.-633C>A | 5'UTR (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
